Somatic mutation profile of tumor specimen TCGA-66-2766-01A (aliquot TCGA-66-2766-01A-01D-1522-08) from TCGA case TCGA-66-2766, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.2 years (19,814 days).
Specimen TCGA-66-2766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44d0de5c-e56a-4b4a-8314-1a9a31449048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2766-11A (Solid Tissue Normal), aliquot TCGA-66-2766-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7551f5ee-3f44-46f9-b94d-51921d2653c8

The open-access MAF lists 417 somatic variants for this specimen: 312 protein-altering or splice-affecting, 99 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 272, Silent 99, Nonsense Mutation 20, Splice Site 7, Frame Shift Del 6, Intron 4, Frame Shift Ins 3, Splice Region 3, Translation Start Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FH | c.1052C>A p.S351* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as rs1060500896, COSV63817434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 51/96 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 71/305 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 60/78 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58049029, COSV58052297; called by muse, mutect2, varscan2
- ACADS | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085210, COSV54367929; called by muse, mutect2, varscan2
- ACER1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774677805, COSV56834515; called by muse, mutect2, varscan2
- ACSS3 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083642; called by muse, mutect2, varscan2
- ACVRL1 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.541); catalogued as COSV66359453; called by muse, mutect2, varscan2
- ADAMTS6 | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 105/155 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs780850470, COSV58681461; called by muse, mutect2, varscan2
- ADCY4 | c.2726T>C p.F909S | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60251596; called by muse, mutect2, varscan2
- ADGRL2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54649521; called by muse, mutect2, varscan2
- AHCTF1 | c.3970C>G p.Q1324E (on ENST00000366508; = p.Q1298E on NM_015446.5) | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV58245230; called by muse, mutect2, varscan2
- AHNAK | c.7133A>T p.D2378V | Missense Mutation (SNP) | VAF 258/478 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV57202201; called by muse, mutect2, varscan2
- AKAP13 | c.2827T>C p.S943P | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63447391; called by muse, mutect2, varscan2
- AKAP4 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 104/135 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as COSV62073502; called by muse, mutect2, varscan2
- ALDOB | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs752633158, COSV66397201, COSV66398226; called by muse, mutect2, varscan2
- AMER3 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV58464864; called by muse, mutect2
- AMFR | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV51919557; called by muse, mutect2, varscan2
- ANKRD11 | c.5391G>T p.R1797S | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56353546; called by muse, mutect2, varscan2
- ANLN | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56073520; called by muse, mutect2, varscan2
- APAF1 | c.945A>T p.K315N (on ENST00000551964 / NM_181861.2; = p.K304N on NM_001160.3) | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV59661198; called by muse, mutect2, varscan2
- APPL2 | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV51587668; called by muse, mutect2, varscan2
- ARHGAP29 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53107575, COSV53116559; called by muse, mutect2, varscan2
- ARHGEF4 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | catalogued as COSV58117070; called by muse, mutect2, varscan2
- ARID4A | c.2442G>T p.Q814H | Missense Mutation (SNP) | VAF 110/148 reads (74%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.862); catalogued as COSV62161726, COSV62162431; called by muse, mutect2, varscan2
- ASB5 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 167/222 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV56668218; called by muse, mutect2, varscan2
- ATP10D | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 132/512 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56703118; called by muse, mutect2, varscan2
- ATP2B2 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV59487916; called by muse, mutect2, varscan2
- ATP6V0D1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs200216007, COSV52096523; called by muse, mutect2, varscan2
- B3GALT1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907874; called by muse, mutect2, varscan2
- BCLAF1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs148729378; called by muse, mutect2, varscan2
- BHMT | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57153238, COSV99165572; called by muse, mutect2, varscan2
- BRINP3 | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100818196, COSV66511378; called by muse, mutect2, varscan2
- BRSK1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 73/93 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV58664360; called by muse, mutect2, varscan2
- C4orf19 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52648807; called by muse, mutect2, varscan2
- CACNA1E | c.6792C>A p.N2264K (on ENST00000367573 / NM_001205293.3; = p.N2221K on NM_000721.4) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV62380977; called by muse, mutect2, varscan2
- CARD18 | c.89T>A p.L30* | Nonsense Mutation (SNP) | VAF 120/163 reads (74%) | catalogued as COSV73233127; called by muse, mutect2, varscan2
- CARM1 | c.1665G>C p.M555I | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV53402590, COSV99450213; called by muse, mutect2, varscan2
- CATSPERB | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 86/117 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56421443; called by muse, mutect2, varscan2
- CATSPERG | c.1667G>A p.W556* | Nonsense Mutation (SNP) | VAF 337/454 reads (74%) | catalogued as COSV53045442; called by muse, mutect2, varscan2
- CCDC102B | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 105/150 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV60133463; called by muse, mutect2, varscan2
- CCDC102B | c.1334C>G p.T445S | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as COSV60133470; called by muse, mutect2, varscan2
- CCSER1 | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV61402573, COSV61433484; called by muse, mutect2, varscan2
- CDH23 | c.1562T>A p.L521Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54922902; called by muse, mutect2
- CDK8 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67419015; called by muse, mutect2, varscan2
- CDKAL1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772332509, COSV51179365; called by muse, mutect2, varscan2
- CDKAL1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV51179370; called by muse, mutect2, varscan2
- CEP192 | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 126/164 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58059376; called by muse, mutect2, varscan2
- CERS4 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781342642, COSV52164925; called by muse, mutect2, varscan2
- CFAP61 | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55617697; called by muse, mutect2, varscan2
- CFL1 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV57448841; called by muse, mutect2, varscan2
- CHKA | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1291342588, COSV55838245; called by muse, mutect2, varscan2
- CHST11 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV57983097, COSV57994169; called by muse, mutect2, varscan2
- CLDN16 | c.274G>T p.G92* | Nonsense Mutation (SNP) | VAF 167/434 reads (38%) | catalogued as COSV53226751; called by muse, mutect2, varscan2
- CLK1 | c.282A>C p.E94D | Missense Mutation (SNP) | VAF 214/497 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58432150; called by muse, mutect2, varscan2
- CNTN5 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54275112; called by muse, mutect2, varscan2
- COL11A1 | c.3539G>T p.G1180V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62171260; called by muse, varscan2
- COL14A1 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52846248; called by muse, mutect2, varscan2
- COL20A1 | c.3365A>T p.Q1122L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV58911043; called by muse, mutect2, varscan2
- COL4A2 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64624255; called by muse, mutect2, varscan2
- COL5A1 | c.2059A>C p.K687Q | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV65664462; called by muse, mutect2
- CPA4 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 51/126 reads (40%) | catalogued as COSV55982139; called by muse, mutect2, varscan2
- CPAMD8 | c.2951G>T p.R984L (on ENST00000651564; = p.R937L on NM_015692.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV71595700; called by muse, mutect2, varscan2
- CR2 | c.842del p.P281Lfs*8 | Frame Shift Del (DEL) | VAF 98/198 reads (49%) | catalogued as rs775000443, COSV65505925; called by mutect2, varscan2
- CRYZ | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61716771; called by muse, mutect2, varscan2
- CUX1 | c.1520G>C p.R507T (on ENST00000437600 / NM_181500.4; = p.R509T on NM_001913.5) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52921854; called by muse, mutect2, varscan2
- CYP11B1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 93/145 reads (64%) | SIFT tolerated (0.65); PolyPhen benign (0.39); catalogued as COSV52824341; called by muse, mutect2, varscan2
- DBH | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775127844, COSV55039525, COSV55041006; called by muse, mutect2, varscan2
- DCAF4L2 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 111/164 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV60476131; called by muse, mutect2, varscan2
- DCDC2B | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV52207218; called by muse, mutect2, varscan2
- DCK | c.779T>G p.L260W | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54377478; called by muse, mutect2, varscan2
- DEFA6 | c.194-2A>G p.X65_splice | Splice Site (SNP) | VAF 48/67 reads (72%) | catalogued as COSV99857856; called by muse, mutect2, varscan2
- DHX8 | c.1431G>C p.M477I | Missense Mutation (SNP) | VAF 202/934 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV52250615; called by muse, mutect2, varscan2
- DLG1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.167); catalogued as COSV58377049; called by muse, mutect2, varscan2
- DNAH11 | c.10241C>T p.T3414M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs779964310, COSV60937035; called by muse, mutect2, varscan2
- DNAH3 | c.7020A>G p.I2340M | Missense Mutation (SNP) | VAF 202/277 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV54500751; called by muse, mutect2, varscan2
- DNAJC14 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 80/429 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV57911973; called by muse, mutect2, varscan2
- DNAJC21 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV57758911; called by muse, mutect2, varscan2
- DSCAML1 | c.3001T>A p.S1001T (on ENST00000321322; = p.S941T on NM_020693.4) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV58380146, COSV58383137; called by muse, mutect2, varscan2
- DTX3L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 135/214 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs748994219, COSV56143082, COSV99949896; called by muse, mutect2, varscan2
- EFNB2 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 127/155 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV55362992, COSV55367456; called by muse, mutect2, varscan2
- EIF3F | c.745+1G>T p.X249_splice | Splice Site (SNP) | VAF 29/68 reads (43%) | catalogued as rs113494623, COSV59141135; called by muse, mutect2, varscan2
- EMSY | c.2684G>C p.G895A | Missense Mutation (SNP) | VAF 142/693 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV58256905, COSV58257441; called by muse, mutect2, varscan2
- EPHA6 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 396/538 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760704852, COSV67556568; called by muse, mutect2, varscan2
- EPRS1 | c.3716G>C p.G1239A | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65096936; called by muse, mutect2, varscan2
- ERICH3 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV58598217; called by muse, mutect2, varscan2
- FAM114A1 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV62671697, COSV62673644; called by muse, mutect2, varscan2
- FAM135B | c.1835T>A p.L612H | Missense Mutation (SNP) | VAF 271/423 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52701917; called by muse, mutect2, varscan2
- FARS2 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51164278; called by muse, mutect2, varscan2
- FASTKD3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.122); catalogued as COSV52941290; called by muse, mutect2, varscan2
- FCRL2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV63832384; called by muse, mutect2, varscan2
- FIGNL1 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1054523452, COSV63553137, COSV63553932; called by muse, mutect2, varscan2
- FKTN | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 152/195 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs775183646, COSV56307835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.2817G>T p.L939F | Missense Mutation (SNP) | VAF 147/169 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54042182; called by muse, mutect2, varscan2
- FREM2 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 104/124 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV54826678; called by muse, mutect2, varscan2
- FSIP2 | c.20710C>A p.Q6904K | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV58077210; called by muse, mutect2, varscan2
- FTO | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.211); catalogued as COSV67109768; called by muse, mutect2, varscan2
- GAP43 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745746040, COSV59342107, COSV59344036; called by muse, mutect2, varscan2
- GJA9 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV62531655; called by muse, mutect2, varscan2
- GJA9 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62531661; called by muse, mutect2, varscan2
- GNE | c.1490G>A p.R497K (on ENST00000396594 / NM_001128227.3; = p.R466K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/150 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1421444537, COSV64951175; called by muse, mutect2, varscan2
- GOLGA4 | c.6550G>C p.E2184Q | Missense Mutation (SNP) | VAF 6/176 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62708890; called by muse, mutect2
- GPA33 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV54801523; called by muse, mutect2, varscan2
- GPC2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV52783645, COSV52786686, COSV99445165; called by muse, mutect2, varscan2
- GPR45 | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 242/563 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV51522561; called by muse, mutect2, varscan2
- GPR78 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66762366; called by muse, mutect2, varscan2
- GPR83 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV54717216; called by muse, mutect2, varscan2
- GRIA3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52047488, COSV52078860; called by muse, mutect2
- GRM5 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV59587957, COSV59605851; called by muse, mutect2, varscan2
- GRM8 | c.2174A>G p.Y725C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1185685926, COSV58797854; called by muse, mutect2, varscan2
- H2BC18 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.716); catalogued as rs782535906, COSV58943636; called by muse, varscan2
- H3C13 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as COSV100516067; called by muse, mutect2, varscan2
- H4C5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63486069; called by muse, mutect2, varscan2
- HENMT1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141386408; called by muse, mutect2, varscan2
- HIPK1 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV61245455; called by muse, mutect2, varscan2
- HIPK2 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as rs1357622639, COSV61225147; called by muse, mutect2, varscan2
- HK1 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53852506; called by muse, mutect2, varscan2
- IGFLR1 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 115/169 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1323039921, COSV53073399; called by muse, mutect2, varscan2
- IGKV3-7 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as rs545887714; called by muse, mutect2, varscan2
- IGLL1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs758781859, COSV50769746; called by muse, mutect2, varscan2
- IGSF11 | c.746C>A p.T249N (on ENST00000393775 / NM_001015887.3; = p.T248N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 417/527 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV61164780; called by muse, mutect2, varscan2
- IL17RA | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV60051044; called by muse, mutect2, varscan2
- INTS5 | c.2297C>A p.S766* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as COSV57950103; called by muse, mutect2, varscan2
- ITGA8 | c.3032C>A p.P1011Q | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65223889; called by muse, mutect2, varscan2
- JADE3 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54463852; called by muse, mutect2, varscan2
- KCNJ9 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV63631397; called by muse, mutect2, varscan2
- KCNK10 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765748005, COSV56638700; called by muse, mutect2
- KCNK10 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 172/221 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs1368825715, COSV56638726; called by muse, mutect2, varscan2
- KCNK10 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 142/179 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56638745; called by muse, mutect2, varscan2
- KCNK4 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60453431; called by muse, mutect2, varscan2
- KCNN3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV55211814; called by muse, mutect2, varscan2
- KCNQ5 | c.1933C>A p.Q645K | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV59647670; called by muse, mutect2, varscan2
- KIAA1958 | c.1769A>G p.Q590R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as rs143861651; called by muse, varscan2
- KIF21B | c.3049G>T p.D1017Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59751661; called by muse, mutect2, varscan2
- KIF5B | c.2184A>T p.K728N | Missense Mutation (SNP) | VAF 135/216 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV56650387; called by muse, mutect2, varscan2
- KLB | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57299807; called by muse, mutect2, varscan2
- KLHL1 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 134/182 reads (74%) | catalogued as rs1430588733, COSV64765927, COSV64770873; called by muse, mutect2, varscan2
- KRT20 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV51423797; called by muse, mutect2, varscan2
- LAMA2 | c.2764G>T p.A922S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV70336967; called by muse, varscan2
- LCE1B | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1292432640, COSV63980019; called by muse, mutect2, varscan2
- LCE1B | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV63980022; called by muse, mutect2, varscan2
- LCE2C | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.974); catalogued as COSV64228206; called by muse, mutect2, varscan2
- LCE3A | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV59550292; called by muse, mutect2, varscan2
- LDOC1 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.57); PolyPhen benign (0.144); catalogued as COSV65159065; called by muse, mutect2, varscan2
- LDOC1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV65159069; called by muse, mutect2, varscan2
- LMBR1 | c.1388-1G>T p.X463_splice | Splice Site (SNP) | VAF 176/399 reads (44%) | catalogued as COSV100626618; called by muse, mutect2, varscan2
- LRP1B | c.8506G>A p.E2836K | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67181917; called by muse, mutect2, varscan2
- LRP1B | c.4238G>C p.G1413A | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV67181921; called by muse, mutect2, varscan2
- LRP2 | c.5927C>A p.T1976N | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV55538784; called by muse, mutect2, varscan2
- LTBP4 | c.3286G>A p.E1096K (on ENST00000308370 / NM_001042544.1; = p.E1059K on NM_003573.2) | Missense Mutation (SNP) | VAF 239/1066 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52575215; called by muse, mutect2, varscan2
- MARCHF7 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 155/538 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52027190; called by muse, mutect2, varscan2
- MCHR2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs772514447, COSV55999048; called by muse, mutect2, varscan2
- MDN1 | c.4915C>G p.L1639V | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV65516310; called by muse, mutect2, varscan2
- MGAT4C | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV59829286; called by muse, mutect2, varscan2
- MROH2B | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | catalogued as COSV68180626; called by muse, mutect2, varscan2
- MROH2B | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 398/638 reads (62%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV68180631; called by muse, varscan2
- MROH7 | c.1999G>T p.G667W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59867389; called by muse, mutect2, varscan2
- MSR1 | c.401A>T p.N134I | Missense Mutation (SNP) | VAF 230/314 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50506633; called by muse, mutect2, varscan2
- MTIF3 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 85/105 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66949427; called by muse, mutect2, varscan2
- MUC16 | c.3961C>G p.P1321A | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV67440791; called by muse, mutect2, varscan2
- MUC5B | c.4988C>G p.T1663R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV71589671; called by muse, mutect2, varscan2
- MUC5B | c.6827C>G p.T2276S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.112); catalogued as COSV71589672; called by muse, mutect2, varscan2
- MUC5B | c.14989C>T p.P4997S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV71589673; called by muse, mutect2, varscan2
- MUC7 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59216873; called by muse, mutect2, varscan2
- MYH1 | c.4510C>G p.R1504G | Missense Mutation (SNP) | VAF 74/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56842992; called by muse, mutect2, varscan2
- MYH4 | c.5687A>G p.N1896S | Missense Mutation (SNP) | VAF 89/135 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV55111222; called by muse, mutect2, varscan2
- MYO9A | c.3316C>A p.Q1106K | Missense Mutation (SNP) | VAF 99/126 reads (79%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as COSV61846983; called by muse, mutect2, varscan2
- MYRF | c.2693C>T p.P898L (on ENST00000278836 / NM_001127392.3; = p.P863L on NM_013279.4) | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1344416402, COSV53885354; called by muse, mutect2, varscan2
- NCAN | c.3355C>A p.R1119S | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777170009, COSV53046225, COSV99386370; called by muse, mutect2, varscan2
- NCKAP1 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 186/423 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV62939483; called by muse, mutect2, varscan2
- NCOA2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs748237390, COSV71763312; called by muse, mutect2, varscan2
- NID2 | c.2401G>T p.D801Y | Missense Mutation (SNP) | VAF 114/158 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53492374; called by muse, mutect2, varscan2
- NID2 | c.2400G>T p.V800= | Splice Region (SNP) | VAF 114/158 reads (72%) | catalogued as COSV53492384, COSV53502141; called by muse, mutect2, varscan2
- NIN | c.944A>C p.Q315P | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV55379109; called by muse, mutect2, varscan2
- NRG2 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV56828579; called by muse, mutect2, varscan2
- OPA1 | c.587C>T p.A196V (on ENST00000361510 / NM_130837.3; = p.A160V on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100655239; called by muse, mutect2
- OR1S1 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775083801, COSV58705879; called by muse, mutect2, varscan2
- OR2F2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371979913; called by muse, mutect2, varscan2
- OR4A15 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 164/312 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59033435, COSV59036307; called by muse, mutect2, varscan2
- OR51B2 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1359874835, COSV60915820; called by muse, mutect2
- OR52B2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs746886817, COSV73209176; called by muse, mutect2, varscan2
- OR52E8 | c.941A>T p.K314M | Missense Mutation (SNP) | VAF 202/456 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV66204312; called by muse, mutect2, varscan2
- OR5A1 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57375567; called by muse, mutect2
- OR5R1 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 160/325 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs761333374, COSV56571362; called by muse, mutect2, varscan2
- OR6K3 | c.814C>A p.L272I (on ENST00000368146; = p.L256I on NM_001005327.2) | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV63745198, COSV63745666; called by muse, mutect2, varscan2
- P2RY13 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 91/810 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56366958; called by muse, mutect2, varscan2
- PACRGL | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 49/138 reads (36%) | catalogued as COSV54841192; called by muse, mutect2, varscan2
- PCDH11X | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100010434; called by muse, mutect2, varscan2
- PCDH17 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64971326; called by muse, mutect2, varscan2
- PCDHB6 | c.378T>A p.N126K | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50689475; called by muse, mutect2, varscan2
- PCDHGA12 | c.954A>T p.E318D | Missense Mutation (SNP) | VAF 161/217 reads (74%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.044); catalogued as COSV52741829; called by muse, mutect2, varscan2
- PDCD2L | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs143274693, COSV55824443; called by muse, mutect2, varscan2
- PEPD | c.1347C>T p.V449= | Splice Region (SNP) | VAF 50/352 reads (14%) | catalogued as COSV52287017; called by muse, mutect2, varscan2
- PHF21B | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as rs760468264, COSV57555193; called by muse, mutect2, varscan2
- PKHD1 | c.3803C>A p.A1268D | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV61858360; called by muse, mutect2, varscan2
- PKHD1L1 | c.7472G>C p.R2491T | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV65736033, COSV65743771; called by muse, mutect2, varscan2
- PKP2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs775318947, COSV50725802; called by muse, mutect2, varscan2
- PLCL2 | c.427A>G p.M143V (on ENST00000615277 / NM_001144382.2; = p.M17V on NM_015184.5) | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67620363; called by muse, mutect2, varscan2
- PLEKHG4B | c.2759A>G p.Q920R (on ENST00000283426; = p.Q1276R on NM_052909.5) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52042813; called by muse, mutect2
- PODXL2 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 82/101 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV61064407; called by muse, mutect2, varscan2
- POLQ | c.6698C>T p.S2233L | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51744948; called by muse, mutect2, varscan2
- POLQ | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 218/292 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV51744957; called by muse, mutect2, varscan2
- POLQ | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 219/294 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV51744971; called by muse, mutect2, varscan2
- POLR3A | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV64930071; called by muse, mutect2, varscan2
- PPARGC1A | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 143/179 reads (80%) | catalogued as COSV53523769; called by muse, mutect2, varscan2
- PRAME | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV67160838; called by muse, mutect2, varscan2
- PRIMPOL | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV59247711; called by muse, mutect2, varscan2
- PRKG2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 94/354 reads (27%) | catalogued as COSV52318386; called by muse, mutect2, varscan2
- PRUNE2 | c.2116A>C p.K706Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV65037498; called by muse, mutect2, varscan2
- PSD3 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 180/258 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV58960989; called by muse, mutect2, varscan2
- PTCHD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59776225; called by muse, mutect2, varscan2
- RASAL3 | c.2559G>A p.W853* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54604194; called by muse, mutect2
- RASGRF2 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54122089; called by muse, mutect2, varscan2
- RASSF9 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 73/96 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV63432353; called by muse, mutect2, varscan2
- REG1A | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV52068123, COSV99286992; called by muse, varscan2
- RERGL | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1156588983, COSV57460694; called by muse, mutect2, varscan2
- RET | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs1313331250, CM1110094, COSV60685932; called by muse, mutect2, varscan2
- RGL4 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV51943015; called by muse, mutect2, varscan2
- RHOT1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 125/228 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61713376; called by muse, mutect2, varscan2
- RIMS1 | c.2542G>T p.E848* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV53436563; called by muse, mutect2, varscan2
- RPL10L | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751834362, COSV53558471; called by muse, mutect2, varscan2
- RREB1 | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV58552677; called by muse, mutect2, varscan2
- RYR2 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV63657324; called by muse, mutect2, varscan2
- SARDH | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64098300; called by muse, mutect2, varscan2
- SCEL | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62992714; called by muse, mutect2, varscan2
- SCIN | c.2083A>T p.K695* (on ENST00000297029 / NM_001112706.3; = p.K448* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 53/141 reads (38%) | catalogued as COSV51688774; called by muse, mutect2
- SCN10A | c.4960C>G p.L1654V | Missense Mutation (SNP) | VAF 122/171 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71860064; called by muse, mutect2, varscan2
- SCN1A | c.5977A>G p.I1993V (on ENST00000303395 / NM_001202435.3; = p.I1982V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs751750112, COSV57658490; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN1A | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as CM147001, COSV57658506, COSV57664296; called by muse, mutect2, varscan2
- SCN5A | c.1334A>C p.H445P | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV61114779; called by muse, mutect2, varscan2
- SERTAD3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.829); catalogued as COSV100475030, COSV59324462; called by muse, mutect2, varscan2
- SH3GL2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66047226; called by muse, mutect2, varscan2
- SHANK2 | c.5500G>C p.G1834R | Missense Mutation (SNP) | VAF 196/372 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53583660; called by muse, mutect2, varscan2
- SLC24A2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 137/197 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV53856326, COSV53866161; called by muse, mutect2, varscan2
- SLC2A6 | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.099); catalogued as rs781848973, COSV52468531; called by muse, mutect2, varscan2
- SLC32A1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs778809530, COSV54145482; called by muse, mutect2, varscan2
- SLC37A3 | c.1414A>G p.I472V (on ENST00000326232 / NM_001363375.1; = p.Y371C on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV58262433; called by muse, mutect2, varscan2
- SLC44A5 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV63757797; called by muse, mutect2, varscan2
- SLC5A5 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 147/394 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55831295; called by muse, mutect2, varscan2
- SLC8A1 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 160/272 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60469565; called by muse, mutect2, varscan2
- SNAP47 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 64/275 reads (23%) | catalogued as COSV59916704; called by muse, mutect2, varscan2
- SNTG1 | c.363+1G>T p.X121_splice | Splice Site (SNP) | VAF 37/52 reads (71%) | catalogued as COSV52422826; called by muse, mutect2, varscan2
- SOST | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57012074; called by muse, mutect2, varscan2
- SOX5 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58616347; called by muse, mutect2, varscan2
- SPATA17 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV65119075; called by muse, mutect2
- SPEN | c.10606C>G p.R3536G | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV65267809; called by muse, mutect2, varscan2
- SPHKAP | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 81/137 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60867278; called by muse, mutect2, varscan2
- SPTBN4 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58942911; called by muse, mutect2, varscan2
- SPX | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 226/409 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs750496888, COSV57020031; called by muse, mutect2, varscan2
- SWT1 | c.2478G>C p.E826D | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.943); catalogued as COSV62252620; called by muse, mutect2, varscan2
- SYNGR1 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.326); catalogued as rs745901428, COSV99335539; called by muse, mutect2, varscan2
- SYNGR1 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV99335544; called by muse, mutect2, varscan2
- SYT5 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV62829572, COSV62830112; called by muse, mutect2, varscan2
- SYT6 | c.955T>A p.F319I (on ENST00000610222 / NM_001366225.1; = p.F234I on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65772231; called by muse, mutect2, varscan2
- TAFA2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV69171332; called by muse, mutect2, varscan2
- TANC2 | c.3807C>A p.Y1269* | Nonsense Mutation (SNP) | VAF 42/85 reads (49%) | catalogued as COSV67329279; called by muse, mutect2, varscan2
- TBC1D1 | c.2774A>T p.Q925L | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54713316; called by muse, mutect2, varscan2
- TBC1D23 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV61366465; called by muse, mutect2, varscan2
- TDRD6 | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV60173645; called by muse, mutect2, varscan2
- TENM4 | c.7712A>C p.K2571T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV53604195; called by muse, mutect2, varscan2
- THSD7A | c.4826A>G p.Y1609C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68471685; called by muse, mutect2, varscan2
- TLN1 | c.6988G>C p.A2330P | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV59203528; called by muse, mutect2, varscan2
- TMEM132E | c.1556C>A p.T519N (on ENST00000321639; = p.T609N on NM_001304438.2) | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.997); catalogued as COSV58694315, COSV58695588; called by muse, mutect2, varscan2
- TOX3 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54862368; called by muse, mutect2, varscan2
- TPTE | c.1623G>A p.M541I (on ENST00000618007 / NM_199261.4; = p.M523I on NM_199259.4) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758305832; called by muse, mutect2, varscan2
- TRHDE | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV53830330, COSV99669845; called by muse, mutect2, varscan2
- TRPC4 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 79/85 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV58988887, COSV59000757; called by muse, mutect2, varscan2
- TTC13 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV64167619; called by muse, mutect2, varscan2
- TTC17 | c.1938G>C p.L646F | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV50005641; called by muse, mutect2, varscan2
- TTN | c.27542G>C p.R9181T (on ENST00000591111; = p.R8254T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/194 reads (22%) | PolyPhen benign (0.022); catalogued as COSV59861681; called by muse, mutect2, varscan2
- TTN | c.19681G>C p.E6561Q (on ENST00000591111; = p.E5634Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/134 reads (45%) | PolyPhen possibly damaging (0.652); catalogued as rs755499713, COSV59861693; called by muse, mutect2, varscan2
- TYROBP | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 24/156 reads (15%) | catalogued as COSV52887119; called by muse, mutect2, varscan2
- UBE2E3 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV66583695; called by muse, mutect2, varscan2
- UBXN4 | c.1229A>C p.D410A | Missense Mutation (SNP) | VAF 140/257 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55633102; called by muse, mutect2, varscan2
- UNC5D | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54765579; called by muse, mutect2, varscan2
- URGCP | c.1538A>T p.Q513L (on ENST00000453200 / NM_001077663.3; = p.Q504L on NM_017920.4) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56244655; called by muse, mutect2, varscan2
- USP36 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100361473, COSV61749985; called by muse, mutect2, varscan2
- XPO5 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 333/813 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV54827101; called by muse, mutect2, varscan2
- ZBTB3 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67360784, COSV67361584; called by muse, mutect2, varscan2
- ZBTB6 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV65409197, COSV65410847; called by muse, mutect2, varscan2
- ZDHHC17 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58349983; called by muse, mutect2, varscan2
- ZDHHC17 | c.1406G>T p.W469L | Missense Mutation (SNP) | VAF 142/187 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58349990; called by muse, mutect2, varscan2
- ZFP36L2 | c.54A>T p.T18= | Splice Region (SNP) | VAF 56/95 reads (59%) | catalogued as COSV56696858; called by muse, mutect2, varscan2
- ZIC1 | c.591C>G p.Y197* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | catalogued as COSV51550200, COSV99292073; called by muse, mutect2, varscan2
- ZNF208 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV68099457; called by muse, mutect2, varscan2
- ZNF274 | c.1149G>C p.L383F (on ENST00000610905; = p.L278F on NM_016324.3) | Missense Mutation (SNP) | VAF 109/133 reads (82%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV58762705; called by muse, mutect2, varscan2
- ZNF433 | c.1392C>G p.F464L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV61398230; called by muse, mutect2, varscan2
- ZNF438 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 111/619 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1173884587, COSV59191788, COSV59194159; called by muse, mutect2, varscan2
- ZNF44 | c.349G>A p.E117K (on ENST00000356109 / NM_001164276.2; = p.E69K on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/666 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV61134568; called by muse, mutect2, varscan2
- ZNF445 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV68538335; called by muse, mutect2, varscan2
- ZNF536 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs542487578, COSV62817466; called by muse, mutect2, varscan2
- ZNF626 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV74128837; called by muse, varscan2
- ZNF626 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as COSV74128839; called by muse, varscan2
- ZNF626 | c.999A>T p.R333S | Missense Mutation (SNP) | VAF 89/549 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as COSV74128842; called by muse, mutect2, varscan2
- ZNF763 | c.848C>T p.P283L (on ENST00000358987 / NM_001367172.2; = p.P286L on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV59686989; called by muse, mutect2, varscan2
- ZNF80 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 272/327 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1022493294, COSV57359675; called by muse, mutect2, varscan2
- ZNF804B | c.3601C>T p.H1201Y | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV60814498; called by muse, mutect2, varscan2
- ZNF804B | c.3757C>G p.P1253A | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60814506; called by muse, mutect2, varscan2
- CLASP1 | c.3573del p.K1191Nfs*10 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.3241dup p.R1081Kfs*25 (on ENST00000400324 / NM_001042517.2; = p.R818Kfs*25 on NM_030932.3) | Frame Shift Ins (INS) | VAF 67/167 reads (40%) | called by mutect2, pindel, varscan2
- GLP2R | c.75del p.M26Wfs*59 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGKV1-9 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 189/338 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IL2RB | c.378del p.F127Lfs*6 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 395/603 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH6 | c.1058_1083del p.H353Lfs*180 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- POSTN | c.2454dup p.A819Sfs*9 | Frame Shift Ins (INS) | VAF 104/187 reads (56%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.2001del p.I668Ffs*93 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | called by mutect2, pindel, varscan2
- SYNRG | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 103/183 reads (56%) | called by muse, mutect2, varscan2
- TRIM68 | c.427-15_430del p.X143_splice | Splice Site (DEL) | VAF 64/178 reads (36%) | called by mutect2, pindel
- VAV3 | c.2035dup p.R679Kfs*10 | Frame Shift Ins (INS) | VAF 63/212 reads (30%) | called by mutect2, pindel, varscan2
- ABCA10 | c.1149A>G p.P383= | Silent (SNP) | VAF 73/150 reads (49%) | catalogued as COSV52217488; called by muse, mutect2, varscan2
- ACSM2A | c.351T>A p.P117= (on ENST00000219054; = p.P38= on NM_001308169.2) | Silent (SNP) | VAF 40/62 reads (65%) | catalogued as COSV54581657; called by muse, mutect2, varscan2
- ADAMTS4 | c.618A>G p.R206= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV63487160; called by muse, mutect2, varscan2
- ADGRE3 | c.1728C>A p.A576= | Silent (SNP) | VAF 83/165 reads (50%) | catalogued as COSV53728023; called by muse, mutect2, varscan2
- AFF3 | c.297G>T p.G99= | Silent (SNP) | VAF 96/234 reads (41%) | catalogued as COSV57838347; called by muse, mutect2, varscan2
- AOC3 | c.1203G>T p.G401= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV53823893; called by muse, mutect2, varscan2
- APBA2 | c.1263G>T p.G421= | Silent (SNP) | VAF 46/70 reads (66%) | catalogued as rs367808207, COSV67104095; called by muse, mutect2, varscan2
- ARHGAP1 | c.60G>C p.L20= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV61237462; called by muse, mutect2, varscan2
- BRAP | c.1626A>T p.T542= | Silent (SNP) | VAF 114/148 reads (77%) | catalogued as COSV59535243; called by muse, mutect2, varscan2
- CCDC85A | c.936G>T p.G312= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as COSV68147129; called by muse, mutect2, varscan2
- CCHCR1 | c.1557G>A p.L519= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV66182523; called by muse, mutect2, varscan2
- CD248 | c.1875C>T p.S625= | Silent (SNP) | VAF 74/127 reads (58%) | catalogued as rs770987585, COSV60935641; called by muse, mutect2, varscan2
- CFP | c.879C>A p.G293= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as COSV55949557; called by muse, mutect2, varscan2
- CIB3 | c.195G>C p.L65= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV54165330; called by muse, varscan2
- COL12A1 | c.1218C>T p.A406= | Silent (SNP) | VAF 113/448 reads (25%) | catalogued as COSV59388424; called by muse, mutect2, varscan2
- CRLF3 | c.207C>G p.L69= | Silent (SNP) | VAF 166/303 reads (55%) | catalogued as COSV60835135; called by muse, mutect2, varscan2
- CSMD1 | c.2322A>G p.G774= (on ENST00000520002; = p.G773= on NM_033225.6) | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs745825421, COSV59276524; called by muse, varscan2
- DLG5 | c.2304A>T p.A768= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV64946491; called by muse, mutect2
- EDEM1 | c.750C>T p.D250= | Silent (SNP) | VAF 171/386 reads (44%) | catalogued as COSV56580699; called by muse, mutect2, varscan2
- ELF3 | c.99C>T p.A33= | Silent (SNP) | VAF 128/240 reads (53%) | catalogued as COSV62836968; called by muse, mutect2, varscan2
- EPB41L3 | c.3162T>G p.A1054= | Silent (SNP) | VAF 72/107 reads (67%) | catalogued as COSV59442680; called by muse, mutect2, varscan2
- FAT3 | c.11991G>T p.P3997= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs1250948771, COSV53070778, COSV53133042; called by muse, mutect2
- FBXO41 | c.2394G>A p.E798= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54581480; called by muse, mutect2, varscan2
- FPR3 | c.117C>T p.F39= | Silent (SNP) | VAF 105/137 reads (77%) | catalogued as rs369595664; called by muse, mutect2, varscan2
- FRY | c.6594G>A p.T2198= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as rs752351313, COSV66564346; called by muse, mutect2, varscan2
- GABRD | c.297G>A p.R99= | Silent (SNP) | VAF 71/96 reads (74%) | catalogued as COSV66079766; called by muse, mutect2, varscan2
- GCLM | c.600G>A p.L200= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as COSV64686689, COSV64687292; called by muse, mutect2, varscan2
- GEN1 | c.756G>T p.L252= | Silent (SNP) | VAF 58/97 reads (60%) | catalogued as COSV58055055; called by muse, mutect2, varscan2
- GNGT1 | c.12C>T p.I4= | Silent (SNP) | VAF 43/215 reads (20%) | catalogued as COSV50352293; called by muse, mutect2, varscan2
- GPR6 | c.774G>A p.Q258= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV51570845; called by muse, varscan2
- GRM8 | c.2424A>T p.A808= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as COSV58797843; called by muse, mutect2, varscan2
- GSDME | c.765G>T p.L255= | Silent (SNP) | VAF 69/162 reads (43%) | catalogued as COSV61650705; called by muse, mutect2, varscan2
- HTR3E | c.738G>A p.R246= (on ENST00000415389 / NM_001256613.1; = p.R261= on NM_182589.2) | Silent (SNP) | VAF 93/237 reads (39%) | catalogued as rs770545579, COSV58945705; called by muse, mutect2, varscan2
- IGHV4-59 | c.168C>A p.I56= | Silent (SNP) | VAF 102/266 reads (38%) | catalogued as rs782541919; called by muse, mutect2, varscan2
- IGSF10 | c.5640T>C p.D1880= | Silent (SNP) | VAF 46/341 reads (13%) | catalogued as COSV56781102; called by muse, mutect2, varscan2
- IGSF8 | c.1770G>T p.V590= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as COSV58757281; called by muse, mutect2, varscan2
- INHBA | c.999C>T p.I333= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV54219122; called by muse, mutect2, varscan2
- IPO9 | c.2169G>A p.V723= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV64232661; called by muse, mutect2, varscan2
- KDM6B | c.1941C>T p.G647= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV54677429; called by muse, mutect2, varscan2
- KRBA2 | c.156T>C p.Y52= | Silent (SNP) | VAF 86/255 reads (34%) | catalogued as COSV58778578; called by muse, mutect2, varscan2
- KRT16 | c.126C>A p.A42= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs747409722, COSV56966808; called by muse, varscan2
- LAMA3 | c.8169C>T p.I2723= (on ENST00000313654 / NM_198129.4; = p.I1114= on NM_000227.6) | Silent (SNP) | VAF 80/866 reads (9%) | catalogued as COSV52528937; called by muse, mutect2
- LPP | c.1509G>C p.V503= | Silent (SNP) | VAF 46/322 reads (14%) | catalogued as rs373435708; called by muse, mutect2, varscan2
- LRRTM4 | c.1743G>A p.P581= | Silent (SNP) | VAF 115/253 reads (45%) | catalogued as rs754954750, COSV69148953; called by muse, mutect2, varscan2
- LY86 | c.432G>A p.L144= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV57910611; called by muse, mutect2, varscan2
- MC2R | c.699C>A p.A233= | Silent (SNP) | VAF 71/96 reads (74%) | catalogued as COSV59616826, COSV59620245; called by muse, mutect2, varscan2
- MMRN2 | c.2307C>T p.D769= | Silent (SNP) | VAF 57/290 reads (20%) | catalogued as COSV64400310; called by muse, mutect2, varscan2
- MUC16 | c.41391C>T p.F13797= | Silent (SNP) | VAF 46/332 reads (14%) | catalogued as rs1425597879, COSV66689377; called by muse, mutect2, varscan2
- MUTYH | c.858G>T p.V286= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs749815703, COSV58343393; called by muse, mutect2, varscan2
- NPHS1 | c.1368G>T p.R456= | Silent (SNP) | VAF 83/435 reads (19%) | catalogued as rs141962470, COSV62286092; called by muse, mutect2, varscan2
- NRG3 | c.930G>A p.L310= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV64541388; called by muse, mutect2, varscan2
- NUDT17 | c.642G>A p.L214= | Silent (SNP) | VAF 110/180 reads (61%) | catalogued as COSV57906483; called by muse, mutect2, varscan2
- OGFOD2 | c.441G>T p.A147= (on ENST00000228922 / NM_001304833.1; = p.A87= on NM_024623.3) | Silent (SNP) | VAF 78/97 reads (80%) | catalogued as rs375496902, COSV57440476; called by muse, mutect2, varscan2
- OR2F2 | c.366C>A p.R122= | Silent (SNP) | VAF 88/220 reads (40%) | catalogued as COSV68832452; called by muse, mutect2, varscan2
- OR5B2 | c.495T>G p.S165= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV56907341; called by muse, mutect2, varscan2
- P3H1 | c.870A>T p.P290= | Silent (SNP) | VAF 83/146 reads (57%) | catalogued as COSV52531305, COSV52536943; called by muse, mutect2, varscan2
- PAPPA2 | c.1728C>A p.T576= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV62772025; called by muse, mutect2, varscan2
- PATL1 | c.2043G>A p.Q681= | Silent (SNP) | VAF 114/424 reads (27%) | catalogued as COSV55687594; called by muse, mutect2, varscan2
- PCDHB5 | c.1569G>A p.L523= | Silent (SNP) | VAF 64/88 reads (73%) | catalogued as COSV50647134; called by muse, mutect2, varscan2
- PCNT | c.8904C>G p.L2968= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV64024536; called by muse, varscan2
- PHF10 | c.1383T>C p.F461= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV59320820; called by muse, mutect2, varscan2
- PIKFYVE | c.1341G>A p.T447= | Silent (SNP) | VAF 61/236 reads (26%) | catalogued as rs762093065, COSV52236258; called by muse, mutect2, varscan2
- PLG | c.342G>T p.T114= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs776970597, COSV51980374; called by muse, mutect2
- PPFIBP2 | c.2319C>T p.L773= | Silent (SNP) | VAF 90/197 reads (46%) | catalogued as COSV55073892; called by muse, mutect2, varscan2
- PRKDC | c.258A>G p.L86= | Silent (SNP) | VAF 36/45 reads (80%) | catalogued as COSV50621055; called by muse, mutect2, varscan2
- PSME4 | c.639T>C p.Y213= | Silent (SNP) | VAF 189/330 reads (57%) | catalogued as rs193125032, COSV66362911; called by muse, mutect2, varscan2
- PTDSS2 | c.1311A>G p.T437= | Silent (SNP) | VAF 46/61 reads (75%) | catalogued as COSV57276816; called by muse, mutect2, varscan2
- RANBP2 | c.201T>C p.G67= | Silent (SNP) | VAF 148/865 reads (17%) | catalogued as COSV51695479; called by muse, mutect2, varscan2
- RBL2 | c.3208C>A p.R1070= | Silent (SNP) | VAF 100/186 reads (54%) | catalogued as COSV50872691; called by muse, mutect2, varscan2
- RNF146 | c.378A>G p.E126= (on ENST00000368314 / NM_001242850.2; = p.E125= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as COSV58931128; called by muse, mutect2, varscan2
- SLC12A1 | c.2013C>A p.T671= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV66791245; called by muse, mutect2, varscan2
- SLC16A7 | c.1086C>T p.L362= | Silent (SNP) | VAF 109/508 reads (21%) | catalogued as COSV53891526; called by muse, mutect2, varscan2
- SLC17A4 | c.702C>A p.I234= | Silent (SNP) | VAF 140/370 reads (38%) | catalogued as COSV64955447; called by muse, mutect2, varscan2
- SLC22A11 | c.405G>A p.V135= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs753662894, COSV57251534; called by muse, mutect2, varscan2
- SLC44A5 | c.787C>T p.L263= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as COSV63757811; called by muse, mutect2, varscan2
- SLC7A9 | c.129C>T p.I43= | Silent (SNP) | VAF 61/589 reads (10%) | catalogued as COSV50082754; called by muse, mutect2, varscan2
- SPAG16 | c.624A>G p.K208= | Silent (SNP) | VAF 50/69 reads (72%) | catalogued as COSV55982920; called by muse, mutect2, varscan2
- SRCIN1 | c.2706G>T p.P902= (on ENST00000621492; = p.P868= on NM_025248.3) | Silent (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- SRMS | c.813C>A p.A271= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53915713; called by muse, mutect2, varscan2
- STAC | c.1185C>A p.P395= | Silent (SNP) | VAF 62/103 reads (60%) | catalogued as COSV56206020; called by muse, mutect2, varscan2
- SURF4 | c.66G>A p.K22= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV64338645; called by muse, mutect2, varscan2
- SYCP1 | c.1275T>C p.L425= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV65694132; called by muse, mutect2, varscan2
- SYTL5 | c.1371G>A p.R457= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as rs1443438516, COSV52897955; called by muse, mutect2, varscan2
- TCN1 | c.180C>A p.S60= | Silent (SNP) | VAF 214/460 reads (47%) | catalogued as COSV57251854; called by muse, mutect2, varscan2
- TENM1 | c.7773T>C p.T2591= | Silent (SNP) | VAF 114/139 reads (82%) | catalogued as COSV64424018; called by muse, mutect2, varscan2
- TEX15 | c.1647G>A p.V549= (on ENST00000256246; = p.V932= on NM_001350162.2) | Silent (SNP) | VAF 161/216 reads (75%) | catalogued as rs760084341, COSV56340950; called by muse, mutect2, varscan2
- THSD7B | c.1077A>G p.P359= | Silent (SNP) | VAF 78/125 reads (62%) | catalogued as COSV55648507; called by muse, mutect2, varscan2
- TRPV5 | c.2076G>A p.A692= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs777364369, COSV54682716; called by muse, mutect2, varscan2
- TTN | c.67779T>A p.I22593= (on ENST00000591111; = p.I15169= on NM_003319.4) | Silent (SNP) | VAF 105/233 reads (45%) | catalogued as COSV59861650; called by muse, mutect2, varscan2
- TUBB8 | c.1197G>T p.T399= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV100225994; called by muse, mutect2, varscan2
- UBE2E3 | c.591A>T p.I197= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV66583707, COSV66586104; called by muse, mutect2, varscan2
- UNC13A | c.4467G>A p.P1489= | Silent (SNP) | VAF 44/229 reads (19%) | catalogued as rs754427518, COSV53187002; called by muse, mutect2, varscan2
- USP34 | c.8706G>T p.L2902= | Silent (SNP) | VAF 25/237 reads (11%) | catalogued as COSV68397392, COSV68401750; called by muse, mutect2, varscan2
- ZBED9 | c.1410G>A p.Q470= | Silent (SNP) | VAF 109/246 reads (44%) | catalogued as COSV71729128; called by muse, mutect2, varscan2
- ZFAT | c.162A>T p.T54= | Silent (SNP) | VAF 82/130 reads (63%) | catalogued as COSV64733743, COSV64738025; called by muse, mutect2
- ZIC4 | c.507C>A p.A169= | Silent (SNP) | VAF 224/454 reads (49%) | catalogued as COSV67170468, COSV67172242; called by muse, mutect2, varscan2
- ZNF195 | c.135C>T p.L45= | Silent (SNP) | VAF 68/360 reads (19%) | catalogued as COSV50001613; called by muse, mutect2, varscan2
- ZNF608 | c.2682C>T p.P894= | Silent (SNP) | VAF 82/116 reads (71%) | catalogued as COSV100101475, COSV60434832; called by muse, mutect2, varscan2
- ZNF85 | c.297G>A p.V99= | Silent (SNP) | VAF 45/316 reads (14%) | catalogued as rs754912998, COSV56020892; called by muse, mutect2, varscan2
- GALNT10 | c.568+17481G>A | Intron (SNP) | VAF 34/109 reads (31%) | catalogued as COSV51719815; called by muse, mutect2, varscan2
- LCOR | chr10:96828741 T>C | 5'Flank (SNP) | VAF 21/31 reads (68%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71641020 C>G | 3'Flank (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51703885; called by muse, mutect2, varscan2
- MGA | c.1065-4431C>G | Intron (SNP) | VAF 48/133 reads (36%) | catalogued as COSV54947689; called by muse, mutect2, varscan2
- MROH8 | c.370+2496C>A | Intron (SNP) | VAF 12/61 reads (20%) | catalogued as COSV54116555; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2268C>A | Intron (SNP) | VAF 25/144 reads (17%) | catalogued as COSV54092816; called by muse, mutect2, varscan2
